TCGA case TCGA-DU-A5TU — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c095c4a-df97-402e-902c-fc83bcf8ef88

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (2)
1. Astrocytoma, NOS (the primary disease): ICD-O-3 morphology code: 9400/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 62.5 years (22,811 days); Year of diagnosis: 2013; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 796 days (2.2 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Altered Mental Status; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 131 days; Days to treatment end: 166 days; Treatment dose: 54 Gy; Treatment outcome: Progressive Disease; Number of fractions: 27; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 627 days (1.7 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Antiseizure Treatment, preoperative; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 63.0 years (22,997 days); Days to diagnosis: 186 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (4 entries)
- Days to follow up: 47 days; Karnofsky performance status: 50.
- Days to follow up: 111 days; Disease response: With Tumor.
- Day 186 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 796 days (2.2 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Adolescence; Comorbidities: Allergies; Risk factors: Allergy, Eggs.
- Timepoint category: Prior to Diagnosis; Risk factors: Altered Mental Status.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DU-A5TU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 300 mg.
  Slide TCGA-DU-A5TU-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DU-A5TU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DU-A5TU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; History seizures: No; History headaches: No; Symp changes mental status: Yes; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; Related symptom first present: Mental Status Changes; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: Yes; Allergy food diagnosis type: Eggs; Allergy food diagnosis age: 12 - 20 Years; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: No; Family history brain tumor: No; Idh1 mutation test indicator: No; Inherited genetic syndrome indicator: No.
- Drug treatment: Treatment best response: Stable Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: No; Treatment outcome at TCGA followup: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 796 days; disease-specific survival: no event (censored), 796 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 186 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DU-A5TU-01A-11D-A288-01): tumor purity 0.81, ploidy 2.04, whole-genome doublings 0.
